Surgical pathology report (de-identified scan), TCGA case TCGA-10-0928, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-10-0928-01A (Primary Tumor).

[page 1 of 2]
SUPPLEMENTAL REPORT 2

COMMENT:

Immunohistochemical staining for HER-2/neu performed by the HercepTest on a section of right ovarian high grade serous carcinoma (C8) is negative (1+).

This supplemental report is issued to give the results of the immunohistochemical staining; the original diagnosis remains unchanged.

DIAGNOSIS

(A) OMENTUM, BIOPSY:

HIGH GRADE PAPILLARY SEROUS CARCINOMA INVOLVING ADIPOSE TISSUE.

(B) LEFT OVARY AND TUBE, SALPINGO-OOPHORECTOMY:

HIGH GRADE PAPILLARY SEROUS CARCINOMA INVOLVING OVARY AND PARATUBAL SOFT TISSUE.

(C) RIGHT TUBE AND OVARY, SALPINGO-OOPHORECTOMY:

HIGH GRADE PAPILLARY SEROUS CARCINOMA INVOLVING OVARY AND PARATUBAL SOFT TISSUE.

GROSS DESCRIPTION

(A) OMENTUM - A single portion of omentum (28.0 x 7.0 x 3.0 cm) within which several ill-defined white firm, multilobulated tumor nodules are present. Portions of tumor are submitted for frozen section in A1 and A2 with representative sections submitted in A3-A12. Tissue is provided for special studies.

HIGH GRADE PAPILLARY SEROUS CARCINOMA.

(B) LEFT OVARY AND TUBE - A cystic ovary (10 x 10 x 8 cm) with attached unremarkable fallopian tube (6 cm in length and 0.5 cm in greatest diameter). The outer surface of the ovary is tan and smooth. The cyst is filled with straw color fluid. The inner lining contains an area with numerous papillary projections (approximately 25% of surface area). These papillary areas are tan, friable and do not appear to invade. On the outer surface of the fallopian tube there is a single hemorrhagic nodule (0.8 cm). No other lesions are seen. No normal-appearing ovary is present.

SECTION CODE: B1, fallopian tube; B2-B18, tumor with transition into normal; B19, hemorrhagic nodule; B20, unremarkable cyst lining.

[page 2 of 2]
[REDACTED]

(C) RIGHT TUBE AND OVARY - A cystic ovary (12 x 7 x 4 cm) with an attached unremarkable fallopian tube (6 cm in length and 0.5 cm in greatest diameter). The outer surface of the ovary is tan and smooth and focally hemorrhagic. The cyst is filled with clear fluid. The inner lining contains an area of numerous papillary projections (3 x 2 x 1 cm) occupying approximately 10% of the surface area. The remainder of the cyst lining is tan and smooth. A portion unremarkable of normal-appearing ovary is present.

SECTION CODE: C1, fallopian tube; C2, ovary; C3-C9, tumor with transition into normal appearing cyst; C11, representative sections of cyst lining.

[REDACTED]

[REDACTED]

-----END OF REPORT-----

[REDACTED]

Source: NCI Genomic Data Commons file 9633a26d-6117-457a-afcf-94488d9580b4 (TCGA-10-0928.859B2662-493A-4EAD-9AC7-0AA8D0A7A3D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).